Somatic mutation profile of tumor specimen TARGET-10-PARASN-09A (aliquot TARGET-10-PARASN-09A-01D) from TARGET case TARGET-10-PARASN, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.9 years (3,609 days).
Specimen TARGET-10-PARASN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dfd2819b-dbbd-4ed2-81e7-02f891fc33e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARASN-10A (Blood Derived Normal), aliquot TARGET-10-PARASN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af9cfb32-4512-4ca6-a601-2a1d2c78c96b

The open-access MAF lists 10 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Intron 3, Missense Mutation 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM18 | c.1735G>T p.V579L | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.075); catalogued as COSV55845729; called by muse, mutect2, varscan2
- SLC38A10 | c.1768C>T p.Q590* | Nonsense Mutation (SNP) | VAF 29/54 reads (54%) | catalogued as COSV55844481; called by muse, mutect2, varscan2
- PRDM4 | c.1180G>A p.V394M | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- UTP14C | c.853A>T p.I285F | Missense Mutation (SNP) | VAF 57/110 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- P2RY6 | c.399C>A p.A133= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs760542468, COSV62936654; called by muse, mutect2, varscan2
- TLR7 | c.429G>T p.P143= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as rs1341054327, COSV66125842; called by muse, mutect2, varscan2
- ZNF804A | c.2652C>T p.N884= | Silent (SNP) | VAF 13/105 reads (12%) | catalogued as COSV100169408; called by muse, mutect2, varscan2
- NAALADL2 | c.43+4564T>C | Intron (SNP) | VAF 17/50 reads (34%) | called by muse, mutect2
- PPP2R2B | c.-29+34C>T | Intron (SNP) | VAF 24/68 reads (35%) | called by muse, mutect2, varscan2
- TMEM199 | c.286-60G>A | Intron (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
